CPTAC case C3N-03042 — Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/347e22d2-cb00-47d1-bb2d-1b476abdfbe2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Year of birth: 1951; Country of birth: United States.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Overlapping lesion of lip, oral cavity and pharynx; Age at diagnosis: 67.3 years (24,572 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T4a; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Residual disease: RX; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5.2 cm; Lymph node involvement: Positive; Lymph nodes positive: 4; Lymph nodes tested: 41; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03042-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 215 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03042-24: Section location: Oral Cavity; Percent tumor nuclei: 85; Percent necrosis: 5.
- Sample C3N-03042-14: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03042-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: -2 days; Method of sample procurement: Blood Draw.
